Somatic mutation profile of tumor specimen ALCH-B66Y-TTP1-A (aliquot ALCH-B66Y-TTP1-A-1-0-D-A88E-36) from ALCHEMIST case ALCH-B66Y, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 62.5 years (22,837 days).
Specimen ALCH-B66Y-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 35f0f9ad-f753-4734-ba02-ff67f4c3ae6b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B66Y-NB1-A (Blood Derived Normal), aliquot ALCH-B66Y-NB1-A-5-0-D-A88E-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5a834243-addc-41f5-92c9-bbb6c122f99a

The open-access MAF lists 28 somatic variants for this specimen: 19 protein-altering or splice-affecting, 5 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 5, RNA 2, Frame Shift Del 2, Nonsense Mutation 2, 5'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTSV | c.845T>C p.V282A | Missense Mutation (SNP) | VAF 15/492 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV52345293; called by muse, mutect2
- DDX60L | c.5024G>A p.R1675H | Missense Mutation (SNP) | VAF 40/306 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs771464614, COSV52712546, COSV52723736; called by muse, mutect2, varscan2
- DRD4 | c.662G>C p.R221P | Missense Mutation (SNP) | VAF 90/333 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as rs138691183; called by muse, mutect2, varscan2
- FAM184A | c.314G>A p.R105K | Missense Mutation (SNP) | VAF 18/240 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58858949; called by muse, mutect2
- ITPRIPL2 | c.859C>T p.P287S | Missense Mutation (SNP) | VAF 74/269 reads (28%) | SIFT tolerated (0.5); PolyPhen benign (0.406); catalogued as rs541259036, COSV67347878; called by muse, mutect2, varscan2
- TELO2 | c.1648C>T p.R550W | Missense Mutation (SNP) | VAF 71/151 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs758206782, COSV51978925; called by muse, mutect2, varscan2
- ANLN | c.1192C>T p.P398S | Missense Mutation (SNP) | VAF 67/352 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- ANO5 | c.2471A>T p.Q824L | Missense Mutation (SNP) | VAF 53/286 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- CMC2 | c.88A>T p.I30F | Missense Mutation (SNP) | VAF 31/155 reads (20%) | SIFT tolerated (0.71); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HIVEP2 | c.4706T>C p.L1569S | Missense Mutation (SNP) | VAF 116/368 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- HSD17B4 | c.1033del p.A345Qfs*42 (on ENST00000414835 / NM_001199291.3; = p.A320Qfs*42 on NM_000414.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 96/644 reads (15%) | called by mutect2, pindel, varscan2
- ITPR3 | c.2200A>G p.K734E | Missense Mutation (SNP) | VAF 54/176 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.278); called by muse, mutect2
- NOTCH3 | c.2559T>A p.C853* | Nonsense Mutation (SNP) | VAF 46/531 reads (9%) | called by muse, mutect2
- PLD3 | c.1199T>G p.V400G | Missense Mutation (SNP) | VAF 54/243 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SEC23IP | c.1651A>C p.I551L | Missense Mutation (SNP) | VAF 91/263 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- SLITRK1 | c.2065del p.C689Vfs*49 | Frame Shift Del (DEL) | VAF 113/569 reads (20%) | called by mutect2, pindel, varscan2
- SYT17 | c.844G>T p.D282Y | Missense Mutation (SNP) | VAF 103/510 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- THG1L | c.362G>T p.R121I | Missense Mutation (SNP) | VAF 30/183 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- ZNF541 | c.124C>T p.R42* | Nonsense Mutation (SNP) | VAF 130/554 reads (23%) | called by muse, mutect2, varscan2
- MUC12 | c.12309C>A p.G4103= (on ENST00000379442; = p.G3960= on NM_001164462.1) | Silent (SNP) | VAF 202/6103 reads (3%) | called by muse, mutect2
- NRROS | c.378C>T p.A126= | Silent (SNP) | VAF 71/261 reads (27%) | catalogued as rs765772806; called by muse, mutect2, varscan2
- TBC1D12 | c.99C>T p.I33= | Silent (SNP) | VAF 23/366 reads (6%) | called by muse, mutect2
- TLN2 | c.3297G>A p.A1099= | Silent (SNP) | VAF 90/489 reads (18%) | catalogued as rs147953515; called by muse, mutect2, varscan2
- TNFRSF10D | c.837C>T p.T279= | Silent (SNP) | VAF 38/248 reads (15%) | called by muse, mutect2, varscan2
- COILP1 | n.261A>C | RNA (SNP) | VAF 94/526 reads (18%) | called by muse, mutect2, varscan2
- FMO6P | n.1691G>A | RNA (SNP) | VAF 44/265 reads (17%) | called by muse, mutect2, varscan2
- JAKMIP1 | chr4:6048905 T>C | 3'Flank (SNP) | VAF 97/386 reads (25%) | called by muse, mutect2, varscan2
- SERPINC1 | c.-5C>T | 5'UTR (SNP) | VAF 105/481 reads (22%) | catalogued as rs771146323, COSV100875010; called by muse, mutect2, varscan2
